Somatic mutation profile of tumor specimen TCGA-16-0849-01A (aliquot TCGA-16-0849-01A-01W-0424-08) from TCGA case TCGA-16-0849, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.6 years (19,939 days).
Specimen TCGA-16-0849-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e973347-8997-4031-9686-a4a3601f96f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-0849-10A (Blood Derived Normal), aliquot TCGA-16-0849-10A-01W-0424-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5442f31d-8273-4f6c-aa47-72b5b0cbb198

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 13, Nonsense Mutation 8, Frame Shift Ins 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 64/680 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 422/1042 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 262/287 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOT2 | c.34T>G p.S12A | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99468845; called by muse, mutect2, varscan2
- ANPEP | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs10152474; called by muse, mutect2, varscan2
- ATRX | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 194/245 reads (79%) | catalogued as COSV64874953; called by muse, mutect2, varscan2
- CA6 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 110/253 reads (43%) | catalogued as COSV101077373, COSV66261710; called by muse, mutect2, varscan2
- CCDC102B | c.1214A>G p.Q405R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.307); catalogued as COSV100102267; called by mutect2, varscan2
- EML2 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV99839594; called by muse, mutect2
- ESYT1 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0.021); catalogued as COSV99919670; called by muse, mutect2, varscan2
- FUT5 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99398530; called by muse, mutect2, varscan2
- ITGA8 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 64/648 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100959296, COSV65233965; called by muse, mutect2
- LAMA2 | c.6489G>C p.K2163N | Missense Mutation (SNP) | VAF 37/357 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as COSV101370082, COSV70337108; called by muse, mutect2, varscan2
- MAGEA4 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.338); catalogued as COSV99367293; called by muse, mutect2, varscan2
- MEGF10 | c.2374G>A p.G792R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99174718; called by muse, mutect2
- MGAT3 | c.721A>G p.N241D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100361732; called by muse, mutect2, varscan2
- MSH3 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 21/468 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV99432191; called by muse, mutect2
- NELL2 | c.1778T>C p.F593S | Missense Mutation (SNP) | VAF 255/697 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.966); catalogued as COSV100418783; called by muse, mutect2, varscan2
- PPP1R12B | c.2362C>A p.Q788K | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.057); catalogued as COSV99294639; called by muse, mutect2
- PTPDC1 | c.1463G>A p.G488E (on ENST00000375360 / NM_177995.3; = p.G540E on NM_152422.4) | Missense Mutation (SNP) | VAF 24/531 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99997341, COSV99997382; called by muse, mutect2
- RCC2 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100965113; called by muse, mutect2, varscan2
- RIC1 | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs1218604749, COSV99316677; called by muse, mutect2, varscan2
- RNASET2 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1434250650, COSV99218444; called by muse, mutect2, varscan2
- RRAD | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 40/791 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1304477253, COSV55340658; called by muse, mutect2
- RUSC1 | c.798G>A p.W266* | Nonsense Mutation (SNP) | VAF 62/250 reads (25%) | catalogued as COSV99429473; called by muse, mutect2, varscan2
- RXFP1 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 25/139 reads (18%) | catalogued as rs200071060, COSV57055994; called by muse, mutect2, varscan2
- SAP18 | c.266T>C p.F89S (on ENST00000607003; = p.F108S on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/392 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776479725, COSV101229416; called by muse, mutect2, varscan2
- SGMS1 | c.205A>G p.M69V | Missense Mutation (SNP) | VAF 33/843 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100693149; called by muse, mutect2
- SH3D19 | c.1160C>G p.A387G | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV100455510; called by muse, mutect2
- SIRT1 | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 289/640 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.262); catalogued as COSV99281595; called by muse, mutect2, varscan2
- SLC30A4 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99970126; called by muse, mutect2, varscan2
- SMARCA2 | c.3701C>T p.P1234L | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1431264534, COSV100570317; called by muse, mutect2
- SYNE1 | c.17182C>T p.Q5728* (on ENST00000367255 / NM_182961.4; = p.Q5657* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 15/178 reads (8%) | catalogued as COSV55106789, COSV99553913; called by muse, mutect2
- TNFAIP3 | c.1059C>A p.Y353* | Nonsense Mutation (SNP) | VAF 229/867 reads (26%) | catalogued as COSV99396356; called by muse, mutect2, varscan2
- TYRO3 | c.347G>A p.W116* | Nonsense Mutation (SNP) | VAF 33/206 reads (16%) | catalogued as COSV99777200; called by muse, mutect2, varscan2
- UGT2B11 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 28/802 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101485216; called by muse, mutect2
- ZNF160 | c.2193dup p.P732Tfs*5 | Frame Shift Ins (INS) | VAF 227/691 reads (33%) | catalogued as rs745909467; called by mutect2, pindel, varscan2
- RBPJ | c.747dup p.L250Tfs*16 | Frame Shift Ins (INS) | VAF 43/337 reads (13%) | called by mutect2, pindel, varscan2
- ARPIN | c.660G>A p.E220= | Silent (SNP) | VAF 12/254 reads (5%) | catalogued as COSV100673425; called by muse, mutect2
- ATP1A2 | c.1068G>A p.V356= | Silent (SNP) | VAF 62/638 reads (10%) | catalogued as rs1160242709, COSV100767634; called by muse, mutect2
- CCER1 | c.1104C>T p.F368= | Silent (SNP) | VAF 49/137 reads (36%) | catalogued as rs750033012, COSV100726943; called by muse, mutect2, varscan2
- DSG4 | c.1737A>G p.A579= | Silent (SNP) | VAF 39/483 reads (8%) | catalogued as COSV100355349; called by muse, mutect2
- FCER1A | c.111A>G p.P37= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV100929242; called by muse, mutect2, varscan2
- JCAD | c.2262G>A p.R754= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100948079; called by muse, mutect2, varscan2
- MAN2C1 | c.2457G>A p.V819= | Silent (SNP) | VAF 33/978 reads (3%) | catalogued as rs1475834610, COSV99145223; called by muse, mutect2
- OR1L8 | c.231C>T p.S77= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as rs751680804, COSV100508410; called by muse, mutect2, varscan2
- OR2G2 | c.222C>T p.R74= | Silent (SNP) | VAF 11/234 reads (5%) | catalogued as COSV100189577; called by muse, mutect2
- PSG7 | c.1026C>T p.T342= | Silent (SNP) | VAF 257/666 reads (39%) | catalogued as COSV68445546; called by muse, mutect2, varscan2
- RARG | c.1116G>A p.Q372= | Silent (SNP) | VAF 272/743 reads (37%) | catalogued as COSV100553277; called by mutect2, varscan2
- TTC6 | c.1341C>G p.P447= (on ENST00000267368; = p.P1813= on NM_001310135.3) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99941551; called by muse, mutect2, varscan2
- TXLNA | c.573T>G p.A191= | Silent (SNP) | VAF 155/456 reads (34%) | catalogued as COSV101009785; called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472294 C>T | 3'Flank (SNP) | VAF 102/323 reads (32%) | called by muse, varscan2
